Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A168, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A168-01A (Primary Tumor).

[page 1 of 3]
1CB-0-3

Adenocarcinoma, Endometrioid, NOS

8380/3 12/9/10

Site Code: Endometrium C54.1

Surgical Pathology

TISSUE DESCRIPTION:

A1 A2 A3 A4 A5 A6 A7 A8 A9 A10 A11 A12 J1 J2 K1
L1 M1 N1
O1 P1 Q1 R1 S1 B1 B2 B3 B4 B5 B6 B7 B8 B9 T1 U1 V1 V2 C1
C2 C3 C4 C5
C6 C7 C8 D1 E1 E2 F1 G1 G2 G3 G4 H1 H2 H3 I1
Uterus, right ovary (1.7 x 1.3 x 1.0 cm) with 8.3 cm
segment of
right fallopian tube, and left ovary (1.8 x 1.2 x 1.0 cm)
with 7.4
cm segment of left fallopian tube (together weighing 120.0
grams);
portion of omentum (18.4 x 16.2 x 2.2 cm); right and left
pelvic
lymph nodes; right and left para-aortic lymph nodes above
and below
the inferior mesenteric artery; right gonadal vessel (7.4
cm in
length); left gonadal vessel (6.3 cm in length);
separately
submitted staging biopsies [cul de sac peritoneum, left
pelvic
sidewall, bladder peritoneum, right colic gutter, right
pelvic
sidewall, left colic gutter, right hemidiaphragm, large
bowel
serosa, small bowel serosa, large bowel mesentery, small
bowel
mesentery (ranging in size from 0.2 cm to 1.8 cm in
greatest
dimension)]; and appendix (4.2 x 0.8 cm).

DIAGNOSIS:

Uterus, bilateral ovaries, and fallopian tubes; total
abdominal
hysterectomy and bilateral salpingo-oophorectomy: FIGO
grade 3 (of
3) endometrioid adenocarcinoma with extensive squamous
differentiation, forming a polypoid mass (4.8 x 4.3 x 2.1
cm) that
fills the entire endometrial cavity. The tumor invades
0.6 cm into

[page 2 of 3]
the myometrium (total myometrial thickness, 1.7 cm) [AJCC pT16NXMX].

The cervix and serosal surface are not involved. The bilateral ovaries and fallopian tubes are negative for tumor.

Omentum, omentectomy: Negative for tumor.

Lymph nodes, right pelvic, excision: Multiple (10 external iliac, 4 internal iliac, 3 common iliac, 7 obturator) right pelvic lymph nodes are negative for tumor.

Lymph nodes, left pelvic, excision: Multiple (7 external iliac, 1 internal iliac, 11 common iliac, 7 obturator) left pelvic lymph nodes are negative for tumor.

Lymph nodes, left and right para-aortic, excision: Multiple (8 left, 3 right) para-aortic lymph nodes above the inferior mesenteric artery are negative for tumor. Multiple (2 left, 6 right) para-aortic lymph nodes below the inferior mesenteric artery are negative for tumor.

Gonadal vessels, left and right, excision: The left and right gonadal vessels are negative for tumor.

Pelvic peritoneum; cul de sac peritoneum, left pelvic sidewall, bladder peritoneum, right colic gutter, right pelvic sidewall, left colic gutter, right hemidiaphragm, large bowel serosa, small bowel serosa, large bowel mesentery, small bowel mesentery; staging biopsies: Negative for tumor, all specimens.

Appendix, appendectomy: Unremarkable appendix.

[page 3 of 3]
PRELIMINARY FROZEN SECTION CONSULTATION:

~~Uterus~~, bilateral ovaries, and fallopian tubes; total
hysterectomy
and bilateral salpingo-oophorectomy: FIGO grade III (of
III)
endometrial carcinoma, endometrioid type with focal clear
cell
features and extensive squamous differentiation. Hold
over to
confirm on permanent sections.

Source: NCI Genomic Data Commons file de5bd8b3-551a-4f85-81e2-c7fffa44ee1f (TCGA-D1-A168.B9D9D808-17B1-415F-9E58-4FDBC1BF30C0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).